Somatic mutation profile of tumor specimen MP2PRT-PARPVK-TMP1-A (aliquot MP2PRT-PARPVK-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARPVK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.8 years (2,855 days).
Specimen MP2PRT-PARPVK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24e84967-408e-4a12-9c85-dec314be34fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARPVK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARPVK-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d6a6800-9336-4c95-aad4-71d2582a1ff4

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 11, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 54/147 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BEND2 | c.1937G>A p.R646Q | Missense Mutation (SNP) | VAF 46/264 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1400530049, COSV101192217; called by muse, varscan2
- FPGT-TNNI3K | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs79045456, COSV58559364; called by muse, mutect2, varscan2
- GPM6A | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 65/230 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV54554724, COSV99704832; called by muse, mutect2, varscan2
- LDLRAD3 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 34/781 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs897155198, COSV100214821; called by muse, mutect2
- OTUB1 | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 176/424 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs147019398; called by muse, mutect2, varscan2
- RBPJL | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 218/530 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs911393889, COSV59213109; called by muse, mutect2, varscan2
- RETSAT | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 278/671 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as rs753341490; called by muse, mutect2, varscan2
- SLC16A6 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as rs369041151; called by muse, mutect2, varscan2
- TRRAP | c.11164G>T p.D3722Y (on ENST00000359863 / NM_001244580.1; = p.D3693Y on NM_003496.3) | Missense Mutation (SNP) | VAF 306/665 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100705490; called by muse, mutect2, varscan2
- ZIC4 | c.580C>G p.H194D | Missense Mutation (SNP) | VAF 48/702 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BCOR | c.2700C>T p.F900= | Silent (SNP) | VAF 319/1368 reads (23%) | called by muse, mutect2, varscan2
- BECN2 | c.1116C>G p.L372= | Silent (SNP) | VAF 258/589 reads (44%) | called by muse, varscan2
- GPR149 | c.9A>G p.L3= | Silent (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2, varscan2
- TSHZ3 | c.2274G>A p.A758= | Silent (SNP) | VAF 43/838 reads (5%) | catalogued as rs376822944, COSV99550550; called by muse, mutect2
